Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JC-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS 8500.9 hr 3/11/11

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: 1. Multiple organ resection – left breast and axillary tissue

Unit in charge:

Physician in charge:

Material collected on:

Material collected on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Status after intraoperative examination – ca invasivum.

Examination performed on:

Macroscopic description:

Left breast sized 21 x 10 x 5 cm removed along with axillary tissues sized 12 x 7 x 15 cm and a 19 x 10 cm skin flap. Weight 820 g.
Tumour site sized 11 x 7 x 3 cm on the boundary of outer quadrants, 2 cm from the upper boundary, 0.5 cm from the base and 1 cm from the skin.

A post-operative scar visible in the outer quadrant skin with a seam of 7 cm.

Metastatic lymph nodes of 2.5 cm.

Microscopic description:

Invasio carcinomatosa vasorum.

Infiltratio carcinomatosa mamillae.

In the tumour site, singular foci of carcinoma ductale invasivum and lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (UDH)

AXILLARY LYMPH NODES

Metastases carcinomatosa in lymphonodis No IV/XI.

Infiltratio capsulae lymphonodorum.

Histopathological diagnosis:

Carcinoma ductale partim micropapillare invasivum mammae sinistrae. Invasive ductal carcinoma partially micropapillary of the left breast.

Metastases carcinomatosa in lymphonodis axillae (No IV/XI) (NHG2, pT2, pN2a). Cancer metastases in axillary lymph nodes (No IV/XI)

Invasio carcinoma vasorum. Vascular invasion.

Compliance validated by:

Hir AA Discrepancy		☒

Source: NCI Genomic Data Commons file 20ee9f05-9b03-41bf-8b85-178d7aaa56ae (TCGA-D8-A1JC.B4DB830F-BFA4-47F5-94C7-D95984315866.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).